Somatic mutation profile of tumor specimen MMRF_2232_1_BM_CD138pos (aliquot MMRF_2232_1_BM_CD138pos_T1_KHS5U_L09506) from MMRF case MMRF_2232, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 56.1 years (20,478 days).
Specimen MMRF_2232_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1fb1cb29-1140-446a-bd1d-d2e76f9a88ab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2232_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2232_1_PB_Whole_C2_KHS5U_L09505; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a032d30a-4ffa-4266-8808-d46adf6a65d3

The open-access MAF lists 108 somatic variants for this specimen: 33 protein-altering or splice-affecting, 17 silent, 58 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, 3'UTR 29, Silent 17, Intron 9, 5'Flank 8, 5'UTR 7, 3'Flank 4, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD26 | c.2428G>A p.E810K | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as rs1179814530, COSV65776132; called by muse, mutect2, varscan2
- CDK15 | c.443G>A p.R148Q (on ENST00000652192 / NM_001366386.2; = p.R97Q on NM_139158.2) | Missense Mutation (SNP) | VAF 56/135 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs370446004; called by muse, mutect2, varscan2
- DMGDH | c.902G>A p.R301Q | Missense Mutation (SNP) | VAF 83/258 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs747089244; called by muse, mutect2, varscan2
- DNMT3A | c.977G>A p.R326H | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs758881009, COSV53044554, COSV53064654, COSV53087534; called by muse, mutect2, varscan2
- GRM8 | c.1138C>T p.H380Y | Missense Mutation (SNP) | VAF 30/163 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.251); catalogued as COSV58853712; called by muse, mutect2, varscan2
- IFIT2 | c.1126C>T p.R376W | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.642); catalogued as rs367905315; called by muse, mutect2, varscan2
- IGHV2-70 | c.219T>A p.D73E | Missense Mutation (SNP) | VAF 48/54 reads (89%) | SIFT tolerated (0.22); PolyPhen benign (0.028); catalogued as rs181059057; called by muse, varscan2
- IGLL5 | c.82C>A p.L28M | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.031); catalogued as rs148489860, COSV73248966, COSV73250113; called by muse, mutect2, varscan2
- IGLV3-1 | c.137T>G p.L46W | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs1209327331; called by muse, varscan2
- IGLV3-1 | c.146A>T p.K49I | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as rs61731694; called by muse, varscan2
- IGLV3-1 | c.241T>G p.S81A | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.632); catalogued as rs752066775; called by muse, varscan2
- SHANK3 | c.2981C>T p.A994V | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.29); PolyPhen benign (0.028); catalogued as rs983238111; called by muse, mutect2, varscan2
- TMEM213 | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 110/364 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as rs763336540; called by muse, mutect2, varscan2
- WDR81 | c.4960G>A p.V1654M (on ENST00000409644 / NM_001163809.2; = p.V603M on NM_152348.4) | Missense Mutation (SNP) | VAF 65/156 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.193); catalogued as rs557408703, COSV58484365; called by muse, mutect2, varscan2
- ADGRF5 | c.379G>C p.G127R | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DNAH5 | c.8251A>C p.T2751P | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- ENDOU | c.202T>A p.L68M (on ENST00000422538 / NM_001172439.2; = p.L27M on NM_006025.4) | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GSTM2 | c.296T>A p.I99N | Missense Mutation (SNP) | VAF 178/367 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, varscan2
- KRT27 | c.1131C>G p.I377M | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- LAMA5 | c.4084_4088del p.T1362Afs*18 | Frame Shift Del (DEL) | VAF 14/41 reads (34%) | called by mutect2, pindel, varscan2
- LETM2 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 17/416 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.071); called by muse, mutect2
- NECTIN2 | c.1282G>A p.G428R | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PADI2 | c.625T>A p.S209T | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- PGM5 | c.1510C>T p.R504W | Missense Mutation (SNP) | VAF 24/395 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PMFBP1 | c.2464G>A p.E822K (on ENST00000537465; = p.E817K on NM_031293.3) | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.442); called by muse, mutect2, varscan2
- PNKP | c.368C>T p.P123L | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- RELCH | c.2276T>C p.L759P | Missense Mutation (SNP) | VAF 57/98 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RYR1 | c.11446C>A p.L3816M | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SPHKAP | c.4817G>T p.R1606M (on ENST00000392056 / NM_001142644.2; = p.R1577M on NM_030623.3) | Missense Mutation (SNP) | VAF 67/143 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- SSRP1 | c.229T>G p.F77V | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TBC1D2B | c.2305G>A p.E769K | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TLR10 | c.260T>C p.L87P | Missense Mutation (SNP) | VAF 67/137 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TTN | c.64067C>T p.T21356I (on ENST00000591111; = p.T13932I on NM_003319.4) | Missense Mutation (SNP) | VAF 41/98 reads (42%) | PolyPhen benign (0.143); called by muse, mutect2, varscan2
- ARHGAP31 | c.525G>A p.A175= | Silent (SNP) | VAF 79/146 reads (54%) | catalogued as rs1304654063, COSV51791446; called by muse, mutect2, varscan2
- BANP | c.774C>T p.Y258= (on ENST00000286122; = p.Y227= on NM_017869.4) | Silent (SNP) | VAF 15/32 reads (47%) | called by muse, mutect2, varscan2
- CRBN | c.27C>T p.D9= | Silent (SNP) | VAF 46/100 reads (46%) | catalogued as rs776519022, COSV99214152; called by muse, mutect2, varscan2
- FREM1 | c.5631G>A p.L1877= | Silent (SNP) | VAF 89/132 reads (67%) | catalogued as rs1472756013, COSV66519531; called by muse, mutect2, varscan2
- GCAT | c.363C>T p.R121= | Silent (SNP) | VAF 22/42 reads (52%) | called by muse, mutect2
- IGHV2-70 | c.339G>A p.T113= | Silent (SNP) | VAF 15/24 reads (63%) | catalogued as rs376111067; called by muse, varscan2
- IGHV2-70 | c.66C>T p.T22= | Silent (SNP) | VAF 48/52 reads (92%) | catalogued as rs368498453; called by muse, mutect2, varscan2
- JPH2 | c.999C>T p.D333= | Silent (SNP) | VAF 57/61 reads (93%) | catalogued as rs371519050, COSV65904055; called by muse, mutect2, varscan2
- KMT2A | c.114G>A p.L38= | Silent (SNP) | VAF 24/41 reads (59%) | catalogued as rs1287203145; called by muse, mutect2, varscan2
- LDB3 | c.1557A>G p.P519= | Silent (SNP) | VAF 60/125 reads (48%) | called by muse, mutect2, varscan2
- PLXDC1 | c.252G>A p.V84= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as rs754739059; called by muse, mutect2, varscan2
- PXDN | c.2655C>T p.C885= | Silent (SNP) | VAF 37/71 reads (52%) | catalogued as rs772500865, COSV53240892; called by muse, mutect2, varscan2
- PXDNL | c.1869T>C p.S623= | Silent (SNP) | VAF 49/134 reads (37%) | called by muse, mutect2, varscan2
- RCSD1 | c.399G>A p.R133= | Silent (SNP) | VAF 116/180 reads (64%) | catalogued as rs1558092730; called by muse, mutect2, varscan2
- SCN5A | c.4212C>T p.N1404= (on ENST00000333535 / NM_198056.3; = p.N1403= on NM_000335.5) | Silent (SNP) | VAF 59/132 reads (45%) | catalogued as rs397517954, COSV100348287; ClinVar: likely benign; called by muse, mutect2, varscan2
- SYBU | c.849C>G p.T283= (on ENST00000276646 / NM_001099754.2; = p.T282= on NM_017786.6) | Silent (SNP) | VAF 54/122 reads (44%) | called by muse, mutect2, varscan2
- TYSND1 | c.150G>A p.G50= | Silent (SNP) | VAF 64/103 reads (62%) | catalogued as rs1037306499; called by muse, mutect2, varscan2
- ACHE | chr7:100896869 G>T | 5'Flank (SNP) | VAF 21/40 reads (53%) | called by muse, mutect2, varscan2
- ASIC2 | c.555+30C>G | Intron (SNP) | VAF 15/23 reads (65%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021488 T>G | 5'Flank (SNP) | VAF 30/74 reads (41%) | called by muse, mutect2, varscan2
- BORCS7 | c.*438A>G | 3'UTR (SNP) | VAF 35/77 reads (45%) | called by muse, mutect2, varscan2
- C4B | chr6:32011003 G>A | 5'Flank (SNP) | VAF 43/88 reads (49%) | catalogued as rs372317258; called by muse, mutect2, varscan2
- CLCN6 | c.*211A>C | 3'UTR (SNP) | VAF 79/144 reads (55%) | called by muse, mutect2, varscan2
- CLCN6 | chr1:11845690 A>T | 3'Flank (SNP) | VAF 11/23 reads (48%) | called by muse, mutect2
- CNTNAP2 | c.*2054G>A | 3'UTR (SNP) | VAF 18/73 reads (25%) | called by muse, mutect2, varscan2
- CPNE5 | c.*546G>T | 3'UTR (SNP) | VAF 30/70 reads (43%) | called by muse, mutect2, varscan2
- CSMD3 | c.9863-21C>T | Intron (SNP) | VAF 30/68 reads (44%) | catalogued as rs765628335; called by muse, varscan2
- DIAPH2 | c.*445G>A | 3'UTR (SNP) | VAF 47/51 reads (92%) | called by muse, mutect2, varscan2
- DIP2B | c.*1575del | 3'UTR (DEL) | VAF 18/50 reads (36%) | called by mutect2, pindel, varscan2
- EMX1 | chr2:72916732 G>A | 5'Flank (SNP) | VAF 36/76 reads (47%) | called by muse, mutect2, varscan2
- EXTL3 | c.-186G>C | 5'UTR (SNP) | VAF 14/50 reads (28%) | called by muse, mutect2, varscan2
- FIGNL1 | c.*316G>A | 3'UTR (SNP) | VAF 19/79 reads (24%) | catalogued as rs1276777949; called by muse, mutect2, varscan2
- FOXL2NB | c.*2643T>C | 3'UTR (SNP) | VAF 3/9 reads (33%) | called by muse, mutect2
- FSHR | c.-57C>T | 5'UTR (SNP) | VAF 18/42 reads (43%) | called by muse, mutect2
- GAS8 | c.1288-186G>A | Intron (SNP) | VAF 11/54 reads (20%) | catalogued as rs775350775; called by muse, mutect2, varscan2
- GLIPR1L2 | c.*1183A>G | 3'UTR (SNP) | VAF 55/92 reads (60%) | catalogued as rs1031558543; called by muse, mutect2, varscan2
- GRM1 | c.*118G>A | 3'UTR (SNP) | VAF 28/59 reads (47%) | called by muse, mutect2, varscan2
- GSN-AS1 | n.2735A>T | RNA (SNP) | VAF 46/135 reads (34%) | called by muse, mutect2, varscan2
- HAND2 | c.-657G>A | 5'UTR (SNP) | VAF 20/50 reads (40%) | called by muse, mutect2, varscan2
- HGF | c.*1180dup | 3'UTR (INS) | VAF 32/103 reads (31%) | called by mutect2, varscan2
- HIF1A | c.*1047C>G | 3'UTR (SNP) | VAF 11/39 reads (28%) | called by muse, mutect2, varscan2
- IGHV2-70D | c.-45A>G | 5'UTR (SNP) | VAF 18/56 reads (32%) | called by muse, mutect2
- IGLL5 | c.-37C>G | 5'UTR (SNP) | VAF 35/58 reads (60%) | catalogued as rs138573360, COSV101597192; called by muse, mutect2, varscan2
- IMPDH1 | chr7:128410155 G>A | 5'Flank (SNP) | VAF 27/74 reads (36%) | called by muse, mutect2, varscan2
- IMPDH1 | chr7:128410156 A>C | 5'Flank (SNP) | VAF 27/73 reads (37%) | called by muse, mutect2, varscan2
- ITLN2 | c.441+95G>A | Intron (SNP) | VAF 16/44 reads (36%) | called by muse, mutect2
- KCNT2 | c.*2308A>C | 3'UTR (SNP) | VAF 39/112 reads (35%) | called by muse, mutect2, varscan2
- KIAA1217 | c.*833G>A | 3'UTR (SNP) | VAF 17/37 reads (46%) | called by muse, mutect2, varscan2
- KLK1 | chr19:50818300 T>G | 3'Flank (SNP) | VAF 32/138 reads (23%) | called by muse, mutect2, varscan2
- KMT2A | c.-4G>A | 5'UTR (SNP) | VAF 45/76 reads (59%) | called by muse, mutect2, varscan2
- LTO1 | c.*1928A>C | 3'UTR (SNP) | VAF 29/56 reads (52%) | called by muse, mutect2, varscan2
- MAPK8IP1 | c.-59C>A | 5'UTR (SNP) | VAF 12/28 reads (43%) | catalogued as rs1406506939; called by muse, mutect2, varscan2
- MIR5195 | chr14:106851396 A>G | 5'Flank (SNP) | VAF 66/121 reads (55%) | called by muse, mutect2, varscan2
- NPAS3 | chr14:33803598 del T | 3'Flank (DEL) | VAF 32/56 reads (57%) | catalogued as rs939714680; called by mutect2, varscan2
- OAS3 | c.*2547C>T | 3'UTR (SNP) | VAF 28/59 reads (47%) | catalogued as rs752239542; called by muse, mutect2, varscan2
- PCDH11X | c.3033+3719T>A | Intron (SNP) | VAF 141/146 reads (97%) | catalogued as COSV53463187; called by muse, mutect2, varscan2
- PCDH7 | c.3174+108T>G | Intron (SNP) | VAF 7/19 reads (37%) | called by muse, mutect2, varscan2
- PDHA1 | c.*1243A>G | 3'UTR (SNP) | VAF 102/105 reads (97%) | catalogued as COSV100135788; called by muse, mutect2, varscan2
- RAB13 | c.480+36A>C | Intron (SNP) | VAF 14/104 reads (13%) | called by muse, mutect2, varscan2
- RAPGEF3 | c.2374-169G>A | Intron (SNP) | VAF 21/65 reads (32%) | called by muse, mutect2, varscan2
- RCC2 | c.*12A>G | 3'UTR (SNP) | VAF 87/199 reads (44%) | called by muse, mutect2, varscan2
- RIMS3 | chr1:40625037 C>A | 3'Flank (SNP) | VAF 47/115 reads (41%) | called by muse, mutect2, varscan2
- RIT1 | c.*1793C>A | 3'UTR (SNP) | VAF 5/58 reads (9%) | called by muse, mutect2
- RNF157 | c.*1753C>A | 3'UTR (SNP) | VAF 30/81 reads (37%) | called by muse, mutect2, varscan2
- SETX | c.*269A>C | 3'UTR (SNP) | VAF 30/87 reads (34%) | called by muse, mutect2, varscan2
- SLC5A7 | c.*1180dup | 3'UTR (INS) | VAF 17/61 reads (28%) | called by mutect2, pindel, varscan2
- TET1 | c.*122A>G | 3'UTR (SNP) | VAF 21/58 reads (36%) | called by muse, mutect2, varscan2
- TNNI3 | c.108+82C>T | Intron (SNP) | VAF 6/12 reads (50%) | catalogued as rs1407331646; called by muse, mutect2
- UBE2N | c.*1878T>C | 3'UTR (SNP) | VAF 17/44 reads (39%) | called by muse, mutect2, varscan2
- USP47 | chr11:11841806 T>G | 5'Flank (SNP) | VAF 58/112 reads (52%) | called by muse, mutect2, varscan2
- VCAN | c.*417A>G | 3'UTR (SNP) | VAF 41/61 reads (67%) | called by muse, mutect2, varscan2
- ZFP42 | c.*391C>A | 3'UTR (SNP) | VAF 4/9 reads (44%) | called by muse, mutect2
- ZNF330 | c.*609A>C | 3'UTR (SNP) | VAF 16/28 reads (57%) | called by muse, mutect2, varscan2
- ZNF367 | c.*1932T>G | 3'UTR (SNP) | VAF 82/119 reads (69%) | called by muse, mutect2, varscan2
- ZSCAN26 | c.*5G>T | 3'UTR (SNP) | VAF 36/75 reads (48%) | called by muse, mutect2, varscan2
